Somatic mutation profile of cancer-model specimen HCM-CSHL-0084-C25-85B (3D Organoid; aliquot HCM-CSHL-0084-C25-85B-01D-A78M-36), derived from the primary tumor of HCMI case HCM-CSHL-0084-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.2 years (26,727 days).
Specimen HCM-CSHL-0084-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6fed03c3-5376-4294-b242-75df8f4fe49e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0084-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0084-C25-11A-11D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e746720-17da-4ec2-a455-244ee071cad2

The open-access MAF lists 77 somatic variants for this specimen: 57 protein-altering or splice-affecting, 11 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 11, Intron 4, 5'UTR 3, Nonsense Mutation 3, In Frame Del 2, Splice Region 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 176/287 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 330/330 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs150380425; called by muse, mutect2, varscan2
- CDC5L | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 179/279 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65176928; called by muse, mutect2, varscan2
- COL6A3 | c.5825C>T p.P1942L | Missense Mutation (SNP) | VAF 234/330 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs150694150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUBN | c.3616G>T p.E1206* | Nonsense Mutation (SNP) | VAF 114/411 reads (28%) | catalogued as COSV64711598, COSV64718159; called by muse, mutect2, varscan2
- DMD | c.5194G>T p.D1732Y | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1174588427; called by muse, mutect2, varscan2
- EGLN2 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs746648993, COSV58280174; called by muse, mutect2, varscan2
- FLNC | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 170/345 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1357772572, COSV57956277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD4A | c.114C>A p.P38= | Splice Region (SNP) | VAF 51/152 reads (34%) | catalogued as COSV99198690; called by muse, mutect2, varscan2
- GPR37 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs763636472, COSV58256275; called by muse, mutect2, varscan2
- HMCN2 | c.11308G>A p.D3770N | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs889018911; called by muse, mutect2, varscan2
- IKBKE | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs150428746; called by muse, mutect2, varscan2
- LAMC3 | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 276/572 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242337882, COSV63092889; called by muse, mutect2, varscan2
- MUC16 | c.16309C>A p.Q5437K | Missense Mutation (SNP) | VAF 13/258 reads (5%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.067); catalogued as COSV67457070; called by muse, mutect2
- MYO15A | c.8911G>A p.V2971M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs745308479; called by muse, mutect2
- NLN | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 174/496 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.124); catalogued as rs373507441; called by muse, mutect2, varscan2
- NOL4 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs114980815; called by muse, mutect2, varscan2
- OLFM4 | c.1114C>A p.R372S | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54576255, COSV54577839, COSV54579863; called by muse, mutect2, varscan2
- PLEKHF2 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1039604415; called by muse, mutect2, varscan2
- PLEKHG4B | c.1384C>G p.R462G (on ENST00000283426; = p.R818G on NM_052909.5) | Missense Mutation (SNP) | VAF 183/693 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV52049808; called by muse, mutect2, varscan2
- SERPINE2 | c.1076-4G>A | Splice Region (SNP) | VAF 44/183 reads (24%) | catalogued as rs567218200; called by muse, mutect2, varscan2
- SLC47A1 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs752921546, COSV54498987; called by muse, mutect2, varscan2
- SNTG2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1466380433; called by muse, mutect2, varscan2
- THBS4 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 152/272 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as rs553602331, COSV63470130; called by muse, mutect2, varscan2
- TMEM239 | c.146G>A p.R49Q (on ENST00000361033 / NM_001318207.1; = p.R6Q on NM_001167670.3) | Missense Mutation (SNP) | VAF 224/459 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.023); catalogued as rs1010843980; called by muse, mutect2, varscan2
- XRRA1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 121/156 reads (78%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs771058686, COSV100369791; called by muse, mutect2, varscan2
- ZDHHC20 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs761488863; called by muse, mutect2, varscan2
- ZFPM1 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100128299; called by muse, mutect2, varscan2
- ACO1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 43/309 reads (14%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1091A>T p.E364V | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGEF7 | c.1577T>G p.L526R (on ENST00000375741 / NM_001113511.2; = p.L348R on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CDKN2A | c.334_337del p.R112Cfs*33 | Frame Shift Del (DEL) | VAF 188/196 reads (96%) | called by mutect2, pindel, varscan2
- CENPU | c.154G>T p.V52F | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CLEC9A | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CLPB | c.238A>G p.T80A | Missense Mutation (SNP) | VAF 38/353 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FAM118B | c.697-15_730del p.X233_splice | Splice Site (DEL) | VAF 49/182 reads (27%) | called by mutect2, pindel
- FATE1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 85/277 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FBN1 | c.6101G>A p.G2034D | Missense Mutation (SNP) | VAF 185/384 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXN1 | c.165_172dup p.E58Afs*247 | Frame Shift Ins (INS) | VAF 38/220 reads (17%) | called by mutect2, varscan2
- FUZ | c.1150C>G p.Q384E | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.124); called by muse, varscan2
- FXR1 | c.353dup p.N118Kfs*2 | Frame Shift Ins (INS) | VAF 109/369 reads (30%) | called by mutect2, pindel, varscan2
- GATA2 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSTA5 | c.133del p.R45Efs*19 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | called by mutect2, pindel, varscan2
- HTT | c.2573_2596del p.N858_R865del | In Frame Del (DEL) | VAF 34/140 reads (24%) | called by mutect2, pindel
- JPH1 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- MYOZ3 | c.437C>G p.P146R | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PAPLN | c.2195C>T p.A732V (on ENST00000554301; = p.A705V on NM_173462.4) | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- PAQR9 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 57/443 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RFPL4AL1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 156/1061 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); called by muse, varscan2
- SLC26A7 | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLF1 | c.984T>G p.H328Q | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2
- SREBF1 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- STMN2 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM14 | c.59G>A p.C20Y | Missense Mutation (SNP) | VAF 109/263 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC7A | c.282_284del p.K94del | In Frame Del (DEL) | VAF 51/298 reads (17%) | called by pindel, varscan2
- ZSCAN5C | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- CREBBP | c.3132A>G p.E1044= | Silent (SNP) | VAF 192/485 reads (40%) | called by muse, mutect2, varscan2
- EDNRB | c.798G>C p.L266= (on ENST00000377211 / NM_001201397.1; = p.L176= on NM_000115.5) | Silent (SNP) | VAF 167/260 reads (64%) | called by muse, mutect2, varscan2
- GDPD3 | c.108C>T p.T36= | Silent (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2
- LPAR6 | c.993G>A p.Q331= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- MYO15A | c.102G>A p.S34= | Silent (SNP) | VAF 156/315 reads (50%) | catalogued as COSV99230580; called by muse, mutect2, varscan2
- OSR1 | c.594C>T p.T198= | Silent (SNP) | VAF 100/382 reads (26%) | catalogued as rs537483235; called by muse, mutect2, varscan2
- PEG3 | c.240C>T p.R80= | Silent (SNP) | VAF 10/249 reads (4%) | called by muse, mutect2
- PHACTR3 | c.237A>G p.K79= | Silent (SNP) | VAF 26/285 reads (9%) | catalogued as rs774807157; called by muse, mutect2
- RFC5 | c.615A>T p.L205= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- SEC14L5 | c.546G>T p.T182= | Silent (SNP) | VAF 76/221 reads (34%) | catalogued as COSV99229472; called by muse, mutect2, varscan2
- TIMM44 | c.211T>C p.L71= | Silent (SNP) | VAF 87/149 reads (58%) | called by muse, mutect2, varscan2
- ACAD8 | c.491-17T>C | Intron (SNP) | VAF 143/466 reads (31%) | called by muse, varscan2
- NACA | c.71-1398A>C | Intron (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- NDUFA2 | c.-41_-25del | 5'UTR (DEL) | VAF 285/617 reads (46%) | called by mutect2, pindel, varscan2
- OAT | c.521-48G>T | Intron (SNP) | VAF 131/329 reads (40%) | called by muse, mutect2, varscan2
- PDE7B | c.711+202G>A | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- SAP30 | c.-66G>A | 5'UTR (SNP) | VAF 73/182 reads (40%) | called by muse, mutect2, varscan2
- SHTN1 | c.*2100G>A | 3'UTR (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- TCP10L2 | n.192C>T | RNA (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- ZNF606 | c.-540C>T | 5'UTR (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
